Somatic mutation profile of tumor specimen 0DTUIR from CCDI case PBCKCE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (762 days).
Specimen 0DTUIR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c8abec1-55b0-4da9-a76f-6bf2d6e0d77e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUI2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/711421d9-07e5-4547-877c-bf9de90fda9d

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'UTR 1, Intron 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.589C>T p.Q197* (on ENST00000263121; = p.Q243* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 424/494 reads (86%) | catalogued as CM147152, COSV54094723; called by muse, mutect2, varscan2
- ZNF292 | c.3176A>G p.N1059S | Missense Mutation (SNP) | VAF 30/647 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200889439; called by muse, mutect2
- FBLN1 | c.1174G>C p.G392R | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); called by muse, mutect2
- NLRP9 | c.2961G>C p.R987S | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- NUP98 | c.5238C>T p.D1746= (on ENST00000359171 / NM_001365126.1; = p.D1729= on NM_016320.5 and 4 other RefSeq transcripts) | Splice Region (SNP) | VAF 41/456 reads (9%) | called by muse, mutect2
- BRINP2 | c.1029G>T p.L343= | Silent (SNP) | VAF 40/411 reads (10%) | called by muse, mutect2, varscan2
- DNAH11 | c.10410C>T p.N3470= | Silent (SNP) | VAF 288/714 reads (40%) | catalogued as rs746707590, COSV100175988; called by muse, mutect2
- KCNA2 | c.*1184C>T | 3'UTR (SNP) | VAF 202/465 reads (43%) | called by muse, mutect2, varscan2
- PHYHIPL | c.596+16A>T | Intron (SNP) | VAF 122/315 reads (39%) | called by muse, mutect2, varscan2
